Somatic mutation profile of tumor specimen TCGA-55-7725-01A (aliquot TCGA-55-7725-01A-11D-2167-08) from TCGA case TCGA-55-7725, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.0 years (24,848 days).
Specimen TCGA-55-7725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae8bbb73-9bc2-4347-a7f5-8e57de1668ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7725-10A (Blood Derived Normal), aliquot TCGA-55-7725-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c85e7461-3613-4c69-bf55-aa8e8fe191ad

The open-access MAF lists 154 somatic variants for this specimen: 115 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 34, Frame Shift Del 9, Nonsense Mutation 8, Splice Site 4, Frame Shift Ins 4, Intron 4, Splice Region 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ZEB2 | c.3137C>A p.S1046* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs797046121, COSV57966466; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1483A>T p.M495L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV60694213; called by muse, mutect2, varscan2
- ACTN2 | c.579C>G p.H193Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63978347; called by muse, mutect2, varscan2
- ACVR1C | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54649953; called by muse, mutect2, varscan2
- ADAM18 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767774627, COSV55843788, COSV55855271; called by muse, mutect2
- AKR1C4 | c.813C>A p.S271R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54125665; called by muse, mutect2, varscan2
- ALDH1L1 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56419417; called by muse, mutect2, varscan2
- ANK2 | c.5287A>T p.I1763F | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as COSV52189177; called by muse, mutect2, varscan2
- ARID1A | c.1165A>T p.K389* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV61380820, COSV61389280; called by muse, mutect2, varscan2
- ARSI | c.1353C>A p.N451K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV60818526; called by mutect2, varscan2
- ASB5 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV56674543, COSV99642265; called by muse, mutect2, varscan2
- B4GALT5 | c.195T>G p.Y65* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV65495287; called by muse, mutect2, varscan2
- BCHE | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52255342; called by muse, mutect2, varscan2
- BCLAF1 | c.2614G>T p.G872C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50357681, COSV50361095; called by muse, mutect2
- BGN | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV59038414; called by muse, mutect2, varscan2
- BICD1 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV55688073, COSV55688385; called by muse, mutect2, varscan2
- BST1 | c.611+2T>A p.X204_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53948982; called by mutect2, varscan2
- C5orf15 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV99198341; called by muse, mutect2, varscan2
- CFHR4 | c.220C>A p.Q74K (on ENST00000367416 / NM_001201551.2; = p.Q75K on NM_006684.5) | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.232); catalogued as COSV52235731; called by muse, mutect2, varscan2
- CKAP5 | c.5389A>G p.M1797V (on ENST00000529230 / NM_001008938.4; = p.M1737V on NM_014756.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56374125; called by muse, mutect2, varscan2
- CLMN | c.2408G>T p.G803V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV54188563; called by muse, mutect2, varscan2
- COL5A3 | c.1930G>T p.G644* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV53419415; called by muse, mutect2, varscan2
- COL7A1 | c.3938C>T p.A1313V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV60403264; called by muse, mutect2, varscan2
- CPVL | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV55308823; called by muse, mutect2, varscan2
- CRAMP1 | c.2636G>T p.R879L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99246236; called by muse, mutect2, varscan2
- CTSG | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV53536906; called by muse, mutect2, varscan2
- CYP4F12 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as COSV100215969, COSV61176757; called by muse, mutect2, varscan2
- DCN | c.640A>T p.S214C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV50009357; called by muse, mutect2, varscan2
- EIF3L | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV67740135; called by muse, mutect2, varscan2
- EPHA4 | c.2688C>A p.S896= | Splice Region (SNP) | VAF 51/158 reads (32%) | catalogued as COSV104387061, COSV56044410; called by muse, mutect2, varscan2
- EPS15L1 | c.1917C>T p.G639= | Splice Region (SNP) | VAF 40/104 reads (38%) | catalogued as rs1400547317, COSV50175641; called by muse, mutect2, varscan2
- FLNC | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV57965231; called by muse, mutect2, varscan2
- FOXK1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138350134; called by muse, mutect2, varscan2
- FUNDC2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV65671689; called by muse, mutect2, varscan2
- GLI1 | c.938C>A p.S313* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57367595; called by muse, mutect2, varscan2
- GRAMD1B | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59210797; called by muse, mutect2, varscan2
- GRIA3 | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52080739; called by muse, mutect2, varscan2
- GRIPAP1 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV64553452; called by muse, mutect2, varscan2
- HEATR5A | c.4736T>C p.M1579T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV66345742; called by muse, mutect2, varscan2
- HIP1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029916875, COSV61191586; called by muse, mutect2, varscan2
- HOOK3 | c.1688A>G p.Q563R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV56888034; called by muse, mutect2, varscan2
- HRH2 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51576380; called by muse, mutect2, varscan2
- INSC | c.65del p.G22Efs*27 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV65412110; called by mutect2, pindel, varscan2
- ITPR3 | c.7051C>T p.R2351C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450982494, COSV65291600; called by muse, mutect2, varscan2
- KCNA6 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs763497895, COSV54978054; called by muse, mutect2, varscan2
- KCNJ3 | c.1076A>T p.K359I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54544846; called by muse, mutect2, varscan2
- KIF1A | c.693C>G p.D231E | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV57491129, COSV57496549; called by muse, varscan2
- KIF4A | c.1895C>A p.T632N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV65545967; called by muse, mutect2, varscan2
- KLHL1 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.547); catalogued as rs902696368, COSV64767138, COSV64784452; called by muse, mutect2, varscan2
- LILRB2 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV58748365; called by muse, mutect2, varscan2
- LINGO2 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV58064518; called by muse, mutect2, varscan2
- LRRC2 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56126241, COSV56128465; called by muse, mutect2, varscan2
- MAGEC1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV53581834; called by muse, varscan2
- MAPKAPK3 | c.1101A>T p.K367N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV63598571; called by muse, mutect2, varscan2
- MAZ | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1028155115, COSV50718629; called by muse, mutect2, varscan2
- MS4A4A | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV59703464; called by muse, mutect2, varscan2
- MUC16 | c.41005G>T p.G13669C | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV66696685; called by muse, varscan2
- MUC16 | c.27266C>A p.T9089K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV67494900; called by muse, mutect2, varscan2
- NALCN | c.3886-1G>C p.X1296_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | catalogued as COSV51965908; called by muse, mutect2, varscan2
- NAV3 | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs770714306, COSV57112736; called by muse, mutect2, varscan2
- NOX4 | c.1616+1G>T p.X539_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54465025, COSV99057722; called by muse, mutect2
- NPAP1 | c.2437G>T p.A813S | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.048); catalogued as COSV61511418; called by muse, mutect2, varscan2
- NPM1 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV51577788; called by muse, mutect2, varscan2
- NTNG1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV64279322; called by muse, mutect2, varscan2
- OR2T5 | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63540786; called by muse, mutect2, varscan2
- OR8H1 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV57295982; called by muse, mutect2, varscan2
- OR8K5 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100537259, COSV57891286; called by muse, mutect2, varscan2
- OR8U1 | c.890T>A p.V297E | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100164041; called by muse, mutect2, varscan2
- PCDH18 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs149770317; called by muse, mutect2, varscan2
- PDE11A | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV53708927; called by muse, mutect2, varscan2
- PGM5 | c.302C>A p.T101K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67165154; called by muse, mutect2, varscan2
- PHEX | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as COSV65079147; called by muse, mutect2, varscan2
- PRAMEF17 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282010375; called by muse, mutect2, varscan2
- PTCH1 | c.2936A>G p.N979S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs758907408, COSV59494335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL1 | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs765557084, COSV53105793; called by muse, varscan2
- RC3H2 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs770254107, COSV61802517; called by muse, mutect2, varscan2
- RGS18 | c.117C>A p.I39= | Splice Region (SNP) | VAF 10/41 reads (24%) | catalogued as COSV66507062, COSV66510135; called by muse, mutect2, varscan2
- RS1 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV66107487; called by muse, mutect2, varscan2
- RXFP1 | c.1550del p.P517Lfs*5 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV100313737; called by mutect2, pindel, varscan2
- SIGLEC12 | c.428-2A>T p.X143_splice (on ENST00000291707 / NM_053003.4; = p.T24= on NM_033329.2) | Splice Site (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52465369; called by muse, mutect2, varscan2
- SLC18A3 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs563318974, COSV60330097, COSV60333308; called by muse, mutect2, varscan2
- SLC2A2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58588669; called by muse, mutect2
- SLC46A3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs925210527, COSV57184801; called by muse, mutect2, varscan2
- SNAP91 | c.1938T>A p.F646L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV52134526; called by muse, mutect2, varscan2
- SNTG1 | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52473166; called by muse, mutect2, varscan2
- SPEF2 | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV61553708; called by muse, mutect2, varscan2
- SPTA1 | c.2683C>A p.L895I | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759643; called by muse, mutect2, varscan2
- TBX15 | c.1709G>T p.S570I (on ENST00000369429 / NM_001330677.2; = p.S464I on NM_152380.3) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV52876557; called by muse, mutect2, varscan2
- TMEM132D | c.755C>G p.T252R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV70620013; called by muse, mutect2, varscan2
- TMEM181 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201228986, COSV65565932; called by muse, mutect2, varscan2
- TUBAL3 | c.1241G>A p.W414* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV66814744; called by muse, mutect2, varscan2
- UNC13A | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV53210878; called by muse, mutect2, varscan2
- VCAN | c.2632A>G p.K878E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV54116925; called by muse, mutect2, varscan2
- VNN2 | c.191C>A p.A64E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs201471643, COSV58472205, COSV58474266; called by muse, mutect2, varscan2
- ZC3H7B | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV60962549, COSV60964721; called by mutect2, varscan2
- ZCCHC12 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV59572989; called by muse, mutect2, varscan2
- ZNF257 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV71311758; called by muse, mutect2, varscan2
- ZNF491 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1425001378, COSV60058945; called by muse, mutect2, varscan2
- ZNF622 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100433136; called by muse, mutect2, varscan2
- ZNF639 | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781778492, COSV58384690; called by muse, mutect2, varscan2
- ANKS1B | c.2755dup p.I919Nfs*5 (on ENST00000547776 / NM_152788.4; = p.I145Nfs*5 on NM_020140.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- ARHGAP5 | c.1983del p.F662Lfs*7 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- ARID1B | c.2567dup p.G858Rfs*71 | Frame Shift Ins (INS) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ASNSD1 | c.1196_1209del p.K399Tfs*17 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel
- CRK | c.818del p.G273Vfs*66 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.1609dup p.M537Nfs*43 | Frame Shift Ins (INS) | VAF 6/63 reads (10%) | called by mutect2, pindel, varscan2
- FAM47B | c.1728del p.K576Nfs*22 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- FRG2C | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- IGKV2D-30 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- KCNA1 | c.1338del p.S447Lfs*3 | Frame Shift Del (DEL) | VAF 43/174 reads (25%) | called by mutect2, pindel, varscan2
- LILRB3 | c.875del p.G292Afs*25 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- OGT | c.1851+1del | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- SPATA31A1 | c.2922T>A p.S974R | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SSMEM1 | c.601dup p.C201Lfs*36 | Frame Shift Ins (INS) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- CAMK4 | c.501A>T p.P167= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV56683369; called by muse, mutect2, varscan2
- CHST15 | c.1071C>A p.A357= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60565894; called by muse, mutect2, varscan2
- CNGA4 | c.135C>A p.V45= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV56414865; called by muse, mutect2, varscan2
- CYP2J2 | c.661T>C p.L221= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV64607160; called by muse, mutect2, varscan2
- DSG4 | c.1986C>A p.G662= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV57397778; called by muse, mutect2, varscan2
- FAT3 | c.570T>C p.N190= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53174981; called by muse, mutect2
- FNDC5 | c.387G>A p.E129= | Silent (SNP) | VAF 59/196 reads (30%) | catalogued as COSV65106075; called by muse, mutect2, varscan2
- GABPB1 | c.831A>T p.T277= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs775906598, COSV55017687; called by muse, mutect2, varscan2
- GRM6 | c.813C>A p.P271= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV51449659; called by muse, mutect2, varscan2
- JPH2 | c.1008C>T p.R336= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV65905743; called by muse, mutect2, varscan2
- LMLN | c.1539C>T p.N513= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1364565223, COSV57605114; called by mutect2, varscan2
- LPAR1 | c.204A>G p.L68= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs145661148; called by muse, mutect2, varscan2
- LTBP1 | c.3885G>C p.G1295= (on ENST00000404816 / NM_206943.4; = p.G969= on NM_000627.4) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV55385583; called by muse, mutect2, varscan2
- MAGEC1 | c.108G>A p.Q36= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV53581825; called by muse, mutect2, varscan2
- MARS2 | c.318G>T p.A106= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs778409892, COSV56571686, COSV56572450; called by muse, mutect2, varscan2
- MST1R | c.2373G>A p.Q791= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99619285; called by muse, mutect2, varscan2
- MYH1 | c.1071G>T p.G357= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV56857203; called by muse, mutect2, varscan2
- NCF4 | c.357G>T p.L119= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV50628231; called by muse, mutect2, varscan2
- OBSCN | c.13638C>T p.P4546= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52830678; called by muse, mutect2, varscan2
- OR4A16 | c.186C>A p.A62= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV59045132; called by muse, mutect2, varscan2
- OR8K3 | c.525T>C p.S175= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs780853639, COSV57133189; called by muse, mutect2, varscan2
- PCDHGA12 | c.630G>T p.L210= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1213370298, COSV52768610; called by muse, mutect2, varscan2
- PLEC | c.801C>T p.P267= (on ENST00000322810 / NM_201380.4; = p.P157= on NM_000445.5) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs782187697, COSV59695936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR4 | c.276A>G p.Q92= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as rs777940366, COSV57392679; called by muse, mutect2, varscan2
- PSD | c.285G>T p.G95= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV50062024; called by muse, mutect2, varscan2
- SLC19A3 | c.1341A>G p.A447= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV51454913, COSV51455447; called by muse, mutect2, varscan2
- SLC6A8 | c.156C>G p.R52= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53473489; called by muse, mutect2
- SORCS3 | c.930G>T p.V310= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV63825096; called by muse, mutect2, varscan2
- STK32C | c.585G>T p.L195= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV53846052; called by muse, mutect2, varscan2
- THEG | c.300T>A p.P100= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV61074969; called by muse, mutect2, varscan2
- UCK2 | c.436C>A p.R146= | Silent (SNP) | VAF 28/220 reads (13%) | catalogued as COSV100902812, COSV63316864; called by muse, mutect2, varscan2
- USF1 | c.282G>T p.V94= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV57040738; called by muse, mutect2, varscan2
- USH2A | c.14505A>G p.P4835= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV56438416; called by muse, mutect2, varscan2
- ZNF622 | c.684C>T p.D228= | Silent (SNP) | VAF 46/315 reads (15%) | catalogued as rs961943821, COSV58073901; called by muse, mutect2, varscan2
- HLA-DRB9 | n.226A>G | RNA (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- KLK8 | c.71-89G>C | Intron (SNP) | VAF 24/61 reads (39%) | catalogued as COSV51593412, COSV99144037; called by muse, mutect2, varscan2
- POLA1 | c.2947-21192G>T | Intron (SNP) | VAF 38/156 reads (24%) | catalogued as rs987119492; called by muse, mutect2, varscan2
- RBFOX1 | c.931-5201C>A | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100302666; called by muse, mutect2
- RBFOX1 | c.931-5199T>A | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100302668, COSV100303088; called by muse, mutect2
